Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A1GX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A1GX-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

100-0-3

Adenocarcinoma, endometrioid, NOS
Site: Endometrium c54.1 8380/3

Case Number :

2/1/11
hw

Diagnosis:

A: Uterus, cervix, bilateral tubes and ovaries, hysterectomy, bilateral salpingo-oophorectomy

Location of tumor: endometrium, anterior and posterior, 5.1 cm in greatest dimension

Histologic type: endometrioid with squamous differentiation and associated calcifications

Histologic grade (FIGO): FIGO grade 2 (architectural grade 2, nuclear grade 2)

Extent of invasion: myometrium

Myometrial invasion: Inner half

Depth: 3 mm Wall thickness: 12 mm Percent: 25%

Serosal involvement: none identified

Lower uterine segment involvement: present, anterior and posterior

Cervical involvement: none identified

Adnexal involvement (see below): present

Other sites: not applicable

Cervical/vaginal margin and distance: widely free of tumor

Lymphovascular Space Invasion: none identified

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 14

Other Pathologic findings: none identified

Tumor estrogen receptor and progesterone receptor immunohistochemistry results:

Estrogen receptor: Positive in 30% of tumor cells; half of positive nuclei 1+, other half 2-3+

Progesterone receptor: Positive in 70% of tumor cells; two thirds of positive nuclei 1+, one third 2-3+

Reviewed Initials	RMT	hw

[page 2 of 5]
AJCC Pathologic stage: pT3a pN0

FIGO (2008 classification) Stage grouping: IIIA

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Ovary, right, oophorectomy:

- Epithelial inclusion cyst and physiologic changes.

Ovary, left, oophorectomy:

- No specific pathologic abnormality.

Fallopian tube, right, salpingectomy:

- Metastatic endometrioid adenocarcinoma, extending from luminal surface into wall of fallopian tube.

Fallopian tube, left, salpingectomy:

- Fragments of endometrioid adenocarcinoma floating free in lumen of fallopian tube (see comment).

B: Lymph nodes, right periaortic, dissection

- Four lymph nodes with no evidence of metastatic carcinoma (0/4).

C: Lymph nodes, left periaortic, dissection

- Two lymph nodes with no evidence of metastatic carcinoma (0/2).

D: Lymph nodes, right pelvic, dissection

- Four lymph nodes with no evidence of metastatic carcinoma (0/4).

E: Lymph nodes, left pelvic, dissection

- Four lymph nodes with no evidence of metastatic carcinoma (0/4).

Comment:

Immunostain for cytokeratin AE1/AE3 was performed on the section containing left fallopian tube (A10) to confirm that the atypical cells in the lumen are epithelial and not inflammatory. The immunostain is strongly positive, supporting the presence of endometrioid adenocarcinoma in the lumen.

Clinical History:

with endometrial cancer.

Gross Description:

Received are five appropriately labeled containers.

Container A is labeled "Uterus, cervix, bilateral tubes and ovaries" .

Adnexa: Yes (left = attached, right = detached)

Weight: 175.6 g

Shape: Pear-shaped

[page 3 of 5]
Block Summary:

- A1 - Cervix anterior
- A2 - Cervix, posterior, bisected section
- A3,A4- Tumor, greatest invasion
- A5 - Tumor, underlying hemorrhagic myometrium
- A6 - Anterior lower uterine segment and tumor
- A7 - Posterior lower uterine segment and tumor
- A8 - Right ovary
- A9 - Right fallopian tube
- A10 - Left ovary and left fallopian tube

Container B is labeled "right periaortic nodes". It holds a 3.1 x 2.8 x 1.5 cm fragment of yellow lobulated adipose tissue. Within the fragment it holds four lymph node candidates measuring up to 3 cm in greatest dimension. The lymph nodes are submitted in three cassettes B1-B3.

Block Summary:

- B1, B2 - One lymph node candidate each cassette
- B3 - Two lymph node candidates

The remaining fat is retained in formalin.

Container C is labeled "left periaortic nodes". It holds multiple fragments of yellow lobulated adipose tissue 1.4 x 1.0 x 0.4 cm in aggregate. These fragments are palpated to reveal two lymph node candidates 0.6 cm in greatest dimension each. The lymph nodes are submitted in C1,

Container D is labeled "right pelvic lymph nodes". It holds a 6.1 x 3.3 x 1.5 cm aggregated of yellow lobulated adipose tissue. Palpated within this specimen are multiple lymph node candidates measuring up to 2 cm in greatest dimension. The lymph node candidates are submitted in four cassettes D1-D4.

Block Summary:

- D1 - Multiple lymph node candidates
- D2 - Two lymph node candidates
- D3, D4 - One lymph node candidate each cassette

The remaining fat is retained in formalin.

Container E is labeled "left pelvic lymph nodes". It holds a 4.1 x 2.8 x 1.3 cm aggregated of yellow lobulated adipose tissue. The specimen has four lymph node candidates; the largest is 2.7 cm in greatest dimension. The lymph node candidates are submitted in five cassettes E1-E5.

Block Summary:

- E1 - One lymph node candidate
- E2 - Two lymph node candidates
- E3-E5 - One lymph node candidate serially sectioned

[page 4 of 5]
Dimensions:

height: 5.2 cm

anterior to posterior width: 7.0 cm

breadth at fundus: 5.0 cm

Serosa: Tan/brown and glistening

Cervix: (Received amputated from the corpus) 2.2 x 1.5 cm, amputated to depth of 2.5 cm, and has a 0.4 cm patent os
length of endocervical canal: 2.3 cm

ectocervix: Tan/white with focal erythema

endocervix: Tan and trabeculated

Endomyometrium:

length of endometrial cavity: 4.0 cm

width of endometrial cavity at fundus: 5.0 cm

tumor findings:

dimensions: 5.1 x 4.0 x 4.0 cm

appearance: Tan/white, soft, friable, exophytic

location and extent: Both anterior and posterior wall

myometrial invasion:

outer one-half:

thickness of myometrial wall at deepest gross invasion: 0.4 cm

other findings or comments: The uninvolved myometrium is notable for a 2.0 cm area of intramyometrial hemorrhage. There is normal appearing endometrium at the anterior and posterior lower uterine segments which is tan/pink firm and up to 0.2 cm thick.

Adnexa:

Right ovary:

dimensions: 1.3 x 0.6 x 0.4 cm

outer surface: Tan/pink, smooth with a single 0.4 cm, in greatest dimension, firm nodule. The nodule in section has a white, firm cut surface.

cut surface: Tan/yellow and firm There is a single 0.4 cm in greatest dimension thin walled watery filled cyst

Right fallopian tube:

dimensions: Fimbriated, 4.0 cm in length x 0.3 cm in diameter

outer surface: Tan pink and glistening

cut surface: Patent unremarkable lumen

other findings:

Left ovary:

dimensions: 1.5 x 0.9 x 0.8 cm

external surface: Tan and smooth

cut surface: Tan, firm and unremarkable

Fallopian tube:

dimensions: 0.8 cm in length x <0.2 cm in diameter

outer surface: Red/brown and glistening

cut surface: pin point apparent lumen

other findings:

Specimen is sampled in ten cassettes A1-A10.

[page 5 of 5]
4
Light Microscopy: Light microscopic examination is performed by Dr.

Signature Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 8781ad61-91f4-4774-a40b-ae9afa187a75 (TCGA-EY-A1GX.4AD600AE-7CE0-4BBA-B4FC-0EB8C460502B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).